HCMI case HCM-WCMC-1340-C54 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f59aaafe-c04e-44f3-9937-89bef164494a

Demographics
Sex at birth: female; Year of birth: 1957; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 64.0 years (23,370 days); AJCC staging edition: 8th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic stage: Stage I; FIGO stage: Stage IIIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No; Sites of involvement: Fallopian Tube, Right.
   Pathology details: Additional pathology findings: Other; Lymph node involvement: Negative; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 15 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 35 days; Days to treatment end: 140 days.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 105 days; Days to treatment end: 115 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Lenvatinib + Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: Lenvatinib/Pembrolizumab; Days to treatment start: 282 days; Days to treatment end: 345 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 366 days (1.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 288.

Molecular and laboratory tests
- ERBB2 (IHC): Equivocal.
- ESR1 (IHC): Negative.
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PGR (IHC): Positive.
- PMS2 (IHC): Positive.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormone replacement therapy type: Progesterone and Estrogen.
- Timepoint category: Initial Diagnosis; Weight: 54 kg; Height: 163 cm; BMI: 20.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-1340-C54-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-1340-C54-01A-01-S2: Section location: Bottom; Percent tumor cells: 10; Percent tumor nuclei: 15; Percent normal cells: 90; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-WCMC-1340-C54-01A-01-S1-HE: Section location: Top; Percent tumor cells: 15; Percent tumor nuclei: 20; Percent normal cells: 85; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-WCMC-1340-C54-12A: Sample type: Saliva; Tissue type: Normal; Specimen type: Saliva; Preservation method: Frozen.
- Sample HCM-WCMC-1340-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
